TCGA case TCGA-BJ-A2N9 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e63d4b3-1b49-4bb9-b64f-001273aae120

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 42.2 years (15,411 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 623 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 3; Measurement unit: Centimeters; Tumor depth measurement: 1.7; Tumor length measurement: 2.5; Tumor width measurement: 1.7.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 42.8 years (15,636 days); Days to diagnosis: 225 days; Prior treatment: Yes.
   Treatment given: Treatment type: I-131 Radiation Therapy; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Days to follow up: 15 days; Disease response: Tumor Free.
- Day 225 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 225 days.
- Days to follow up: 623 days (1.7 years); Disease response: With Tumor.
- Disease response: Persistent Distant Metastasis; Timepoint: Within 3 Months of Surgery.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- RAS, NOS mutation, nos: Negative.
- RET translocation: Negative.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BJ-A2N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-BJ-A2N9-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BJ-A2N9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BJ-A2N9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BJ-A2N9-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-BJ-A2N9-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 60; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: Yes.
- Genotyping results gene mutation not reported reasons: Reasons for Genotypic Analysis not Detected: No BRAF Mutation Detected; Reasons for Genotypic Analysis not Detected: No RAS Mutation Detected; Reasons for Genotypic Analysis not Detected: No RET/PTC Rearrangement Detected.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Clinical status within 3 mths surgery: Persistent distant metastases.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 623 days; disease-specific survival: no event (censored), 623 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 225 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BJ-A2N9-01): tumor purity 0.88, ploidy 2.24, whole-genome doublings 0 (call status: maf_call).
